Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACO6, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACO6-TTP1-A (Primary Tumor).

Submissions:

Left lung, removal

Macroscopic report:

Left lung of gr 300 with the upper lung lobe of cm 16 x 6 x 4.5 and lower lung lobe cm 18 x 6 x 4. The visceral pleura of the two lobes are adherent along the interlobar fissure and in the upper posterior region, in correspondence of which the upper lobe is present a sub - pleural neoformation, greyish of hard-elastic consistency, of 6.2 cm of major axis, a polycyclic margins, retracting the overlying pleura and distant cm 2 from the bronchial margin.

The remaining parenchyma of the upper lobe appears congested; the parenchyma of the lower lobe is free of macroscopically evident alterations.

Isolate 32 peri-bronchial lymph nodes.

(A1 broncho vascular margin; A2-A3 neoplasm upper lobe.- lower lobe adhesions; A4 -A5 pleura - neoplasm; A6 neoplasm; A7 parenchyma remote; A8 - A15 lymph nodes)

Histopathologic Diagnosis:

Acinar adenocarcinoma pulmonary, poorly differentiated G3 (WHO1999) of the upper lung lobe, infiltrating the visceral pleura associated with pictures of acute and chronic pleurisy with visceral - visceral adhesions among upper lobe and lower lobe. No evidence of parenchymal lower lobar neoplastic infiltration.

Margin of broncho - vascular resection and remaining parenchyma free of neoplasm.

Lymph node metastasis in 1 of 32 peribronchial lymph nodes retrieved. Free of metastases the remaining 31 lymph nodes.

Histopathologic staging: pTNM: pT2,N1.

ICD-0-3

adenocarcinoma, acinar 8550/3

Submissions:

- a) lymph nodes of the left main bronchus, removal
- b) lymph nodes aortic arch, removal
- c) lymph node lower pulmonary vein, removal

Site

① lung, upper lobe C34.1

ICD-10

C34.12

hw
10/13/16

Macroscopic report:

- a) three major axis lymph nodes between cm 0.4 and cm 1.2
- b) six major axis lymph nodes between cm 0.4 and cm 1.3
- c) two lymph nodes of cm 0.7 and cm 1 of major axis

Histopathologic diagnosis:

A-C) reactive lymphadenitis in all retrieved lymph nodes

Source: NCI Genomic Data Commons file aa6188fc-b3d0-4633-b66e-cbbb356dfe29 (CDDP-ACO6-TTP1.30EE410E-0A2A-4E60-97A6-26C95F73E856.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).